Somatic mutation profile of tumor specimen TCGA-AA-3556-01A (aliquot TCGA-AA-3556-01A-01D-1953-10) from TCGA case TCGA-AA-3556, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 78.6 years (28,704 days).
Specimen TCGA-AA-3556-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a9c4412-9a42-4907-bff2-3a12dc7c04cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3556-10A (Blood Derived Normal), aliquot TCGA-AA-3556-10A-01D-1953-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb5733ad-7a57-49b6-a12b-fbd36ec45e1a

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 13, Silent 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS2 | c.1834C>T p.R612C | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as rs756757077, COSV52391628; called by muse, mutect2, varscan2
- ADAMTS7 | c.4774C>T p.R1592C | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751363176, COSV66309810; called by muse, mutect2, varscan2
- ANO8 | c.3182G>A p.R1061Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.058); catalogued as rs200466080, COSV99344122; called by muse, mutect2, varscan2
- B3GALT4 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.87); catalogued as COSV101005565; called by muse, mutect2, varscan2
- BCL2L12 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV99880900; called by muse, mutect2, varscan2
- CCDC78 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.442); catalogued as COSV99284469, COSV99284586; called by muse, mutect2, varscan2
- GPR20 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 107/168 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.726); catalogued as rs374341766; called by muse, mutect2, varscan2
- MMAB | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as rs200690789, COSV99904500; called by muse, mutect2, varscan2
- RBM10 | c.2297G>A p.R766H | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100237378, COSV61307707, COSV61309534; called by muse, mutect2, varscan2
- SLC4A1 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs778266623, COSV99293039; called by muse, mutect2, varscan2
- UNC5C | c.61C>A p.Q21K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.007); catalogued as COSV101497797; called by muse, mutect2, varscan2
- UNCX | c.560T>C p.M187T | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV100310213; called by muse, mutect2, varscan2
- ZAP70 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1300937876, COSV99385247; called by muse, mutect2, varscan2
- DIRAS1 | c.45G>A p.A15= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs767906645, COSV100052955, COSV60216503; called by muse, varscan2
- NCOR2 | c.1116G>A p.V372= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as COSV100656955; called by muse, mutect2, varscan2
- PCDHA8 | c.2076G>A p.A692= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs782803227, COSV65325006, COSV65331587; called by muse, mutect2, varscan2
- PCDHA8 | c.2190C>T p.G730= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV100969121; called by muse, mutect2, varscan2
- RAX | c.363C>T p.T121= | Silent (SNP) | VAF 31/143 reads (22%) | catalogued as COSV99900187; called by muse, mutect2, varscan2
- ZNF536 | c.1995C>T p.H665= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100834775, COSV62830115; called by muse, mutect2, varscan2
